TCGA case TCGA-2G-AAFN — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis; Tissue source site: Erasmus MC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/46332d2c-aee8-4a8a-b781-55702082f097

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Netherlands; Age at index: 26 years; Year of birth: 1986; Vital status: Alive.

Diagnoses (1)
1. Embryonal carcinoma, NOS: ICD-O-3 morphology code: 9070/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 26.8 years (9,805 days); Year of diagnosis: 2013; Method of diagnosis: Orchiectomy; AJCC staging edition: 7th; AJCC clinical T: T2; AJCC clinical N: N1; AJCC clinical M: M0; AJCC clinical stage: Stage IIIB; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; IGCCCG stage: Good Prognosis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 773 days (2.1 years); Ajcc serum tumor markers: S2.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: No; Timepoint category: Postoperative.
   Pathology details: Intratubular germ cell neoplasia present: No; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Etoposide; Treatment intent type: Adjuvant; Days to treatment start: 18 days; Days to treatment end: 91 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (4 entries)
- Days to follow up: 389 days (1.1 years); Disease response: Tumor Free.
- Days to follow up: 452 days (1.2 years); Disease response: Tumor Free.
- Days to follow up: 773 days (2.1 years); Disease response: Tumor Free.
- Karnofsky performance status: 80; ECOG performance status: 0; Timepoint: Follow-up.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3: Lactate Dehydrogenase 275; Alpha Fetoprotein 35; Human Chorionic Gonadotropin 65.
- Day 18: Lactate Dehydrogenase 216; Alpha Fetoprotein 76; Human Chorionic Gonadotropin 174.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Fertility history: Conceived 1 or more children by natural conception; Undescended testis history: No.

Family history
- Relative with cancer history: yes; Relationship type: Grandmother; Relationship primary diagnosis: Lung Cancer.
- Relative with cancer history: yes; Relationship type: Natural Mother; Relationship primary diagnosis: Melanoma.
- Relative with cancer history: yes; Relationship type: Other; Relationship primary diagnosis: Cancer.
- Relative with cancer history: no.
- Relative with cancer history: yes; Relationship type: Natural Mother; Relationship primary diagnosis: Cervical Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-2G-AAFN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 150 mg.
  Slide TCGA-2G-AAFN-01A-03-TS3: Section location: Top; Percent tumor cells: 99; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-2G-AAFN-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2G-AAFN-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; History hypospadias: No; History fertility: Fathered > or = 1 child by natural conception; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Postoperative treatment list: Postoperative treatment: Pharmaceutical.
- Stage record: Igcccg stage: Good.
- Primary pathology: Submitted tumor site: Testes; Testis tumor macroextent: Involves testis only; Intratubular germ cell neoplasm: Absent; Lymphovascular invasion: Yes; Post orchi lymph node dissection: No; First treatment success: No Measureable Tumor or Tumor Markers.
- Primary pathology, Histology list, Histology: Histologic diagnosis: Non-Seminoma, Embryonal Carcinoma; Histologic diagnosis percent: 100.
- Primary pathology, Pre orchi serum marker info: Pre orchi LDH: 275; Pre orchi hcg: 65; Pre orchi afp: 35.
- Primary pathology, Post orchi serum marker info: Post orchi LDH: 216; Post orchi hcg: 173.8; Post orchi afp: 76.
- Primary pathology, Molecular test result list: Molecular test result: Lactate Dehydrogenase (LDH) - Normal; Molecular test result: Human Chorionic Gonadotropin (HCG) - Normal; Molecular test result: Alpha Fetaprotein (AFP) - Normal.
- Follow-up form 1: Lost to follow-up: No; Post orchi lymph node dissection: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: No; Post orchi lymph node dissection: No; Tumor status: Tumor free; Treatment outcome first course: No Measureable Tumor or Tumor Markers; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 773 days; disease-specific survival: no event (censored), 773 days; disease-free interval: no event (censored), 773 days; progression-free interval: no event (censored), 773 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-2G-AAFN-01A-31D-A42X-01): tumor purity 0.8, ploidy 3, whole-genome doublings 1.
